Gene-level copy-number profile of tumor specimen TCGA-LG-A6GG-01A from TCGA case TCGA-LG-A6GG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 79.0 years (28,871 days).
Specimen TCGA-LG-A6GG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.b4b18333-6b97-476c-b126-71c3e423a208.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LG-A6GG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e27626dc-671b-432e-8727-09ee0aa35f9f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 2,976; copy number 2: 34,190; copy number 3: 19,133; copy number 4: 3,287; copy number 5: 77; copy number 6: 131; copy number 8: 2; copy number 12: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LG-A6GG-01A-11D-A30U-01): tumor purity 0.84, ploidy 2.45, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:113,353,425–113,492,054, 3 genes: RNU7-165P, AL133482.1, PPIAP39.
- chr16:78,099,430–79,212,667, 1 gene (within-gene range 0–1): WWOX.
- chr16:78,550,739–79,110,882, 12 genes: AC046158.3, AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 212 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,269,983–43,354,466, 4 genes, copy number 6: TMEM125, C1orf210, TIE1, MPL.
- chr1:89,633,140–89,933,250, 1 gene, copy number 5 (within-gene range 2–5): AC093423.3.
- chr1:89,788,914–90,533,472, 12 genes, copy number 5: AC099568.1, AC099568.2, LRRC8D, AL391497.1, RN7SKP272, GEMIN8P4, ZNF326, AL161797.1, AC098656.1, RNU6-695P, AL627316.1, LINC02787.
- chr1:97,933,474–101,026,088, 58 genes, copy number 5–6 (within-gene range 3–6): MIR137HG, BX005019.1, MIR2682, MIR137, AC104453.1, NFU1P2, LINC01776, AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1, PLPPR4, AL365220.1, LINC01708, PALMD, HMGB3P10, FRRS1, RNU4-75P, Y_RNA, AC096949.1, AGL, AC118553.1, SLC35A3, AC118553.2, RNU6-750P, RNU6-1318P, MFSD14A, AC093019.2, SASS6, AC093019.1, TRMT13, LRRC39, DBT, RPL23AP90, BRI3P1, AL445928.2, AL445928.1, RTCA-AS1, RTCA, MIR553, AC104457.1, AC104457.2, CDC14A, BCAS2P2, AL589990.1, GPR88, AC099670.1, LINC01349, AC099670.3, AC099670.2, VCAM1, EXTL2, AC104506.1, SLC30A7, HNRNPA1P68, DPH5, AC093157.2.
- chr1:103,523,562–104,226,678, 13 genes, copy number 6: RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C, AL136455.1, AC092506.1, FTLP17.
- chr1:105,433,994–106,124,564, 8 genes, copy number 6: CDK4P1, LINC01676, SEPTIN2P1, AL512844.2, AL512844.1, LINC01677, AL355306.2, AL355306.1.
- chr1:108,134,043–110,023,742, 72 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:52,872,982–53,366,066, 1 gene, copy number 5 (within-gene range 1–5): SCFD2.
- chr4:53,265,461–53,460,862, 2 genes, copy number 5: RNU6-310P, FIP1L1.
- chr4:53,459,301–53,701,405, 4 genes, copy number 5 (within-gene range 1–5): LNX1, LNX1-AS1, AC095040.1, LNX1-AS2.
- chr4:56,530,606–58,118,070, 30 genes, copy number 5–12 (within-gene range 1–12): THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1.
- chr4:59,833,175–60,038,586, 4 genes, copy number 5: Y_RNA, RNU6-1325P, AC092596.1, AC097655.1.
- chr4:98,251,688–98,443,858, 3 genes, copy number 6: AC019077.1, RAP1GDS1, AC058823.1.

Autosomal genes at a single copy (total copy number 1): 2,976. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
